TCGA case TCGA-49-6745 — Lung Adenocarcinoma (TCGA-LUAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung; Tissue source site: Johns Hopkins. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/9c7875ad-ab71-4d48-b2e3-e4c7a46393e9

Demographics
Sex at birth: male; Race: white; Country of residence at enrollment: United States; Age at index: 82 years; Vital status: Alive.

Diagnoses (2)
1. Papillary adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8260/3; ICD-10 code: C34.1; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 82.5 years (30,133 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC pathologic T: T2a; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIA; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Treatment intent type: Adjuvant; Days to treatment start: 64 days; Days to treatment end: 156 days; Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Prior malignancy of the prostate gland (histology not recorded by GDC).
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 156 days; Disease response: Tumor Free.
- Days to follow up: 522 days (1.4 years); Disease response: Tumor Free.

Molecular and laboratory tests
- KRAS mutation, nos: Negative.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 20.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-49-6745-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.1; Intermediate dimension: 0.7; Shortest dimension: 0.3.
  Slide TCGA-49-6745-01A-01-BS1: Section location: Bottom; Percent tumor cells: 65; Percent tumor nuclei: 70; Percent normal cells: 20; Percent necrosis: 0; Percent stromal cells: 15.
  Slide TCGA-49-6745-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10.
- Sample TCGA-49-6745-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-49-6745-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 2.5; Intermediate dimension: 0.7; Shortest dimension: 0.4.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Adenocarcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Tobacco smoking history indicator: 4; Anatomic organ subdivision: L-Upper; KRAS mutation found: No; KRAS gene analysis indicator: Yes; EGFR mutation status: Yes.
- Drug treatment: Regimen number: 1.
- Drug treatment, Route of administrations: Route of administration: IV.
- Follow-up form: New tumor event diagnosis indicator: No; Tumor status: Tumor free.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Prostate.

GDC annotations on this case (curator notes; quoted as recorded):
- Prior malignancy: Prior malignancy prostate cancer. No systemic chemotherapy or radiation.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 522 days; disease-specific survival: no event (censored), 522 days; progression-free interval: no event (censored), 522 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-49-6745-01A-11D-1854-01): tumor purity 0.24, ploidy 3.83, whole-genome doublings 1.
